Somatic mutation profile of tumor specimen TCGA-L5-A8NR-01A (aliquot TCGA-L5-A8NR-01A-11D-A37C-09) from TCGA case TCGA-L5-A8NR, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 81.4 years (29,730 days).
Specimen TCGA-L5-A8NR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1b45598-1cef-4ba0-8a9b-76f9b67684cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A8NR-11A (Solid Tissue Normal), aliquot TCGA-L5-A8NR-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be3f08e4-9092-4359-8a7a-4bb9c89d388c

The open-access MAF lists 233 somatic variants for this specimen: 160 protein-altering or splice-affecting, 66 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 133, Silent 66, Nonsense Mutation 10, Frame Shift Del 9, Splice Region 3, 3'UTR 2, In Frame Del 2, Intron 2, Splice Site 2, RNA 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 29/84 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as CM002273, COSV55670863; called by muse, mutect2, varscan2
- ABCB1 | c.2744A>C p.K915T | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.98); catalogued as rs1234949048, COSV55945450, COSV55964424; called by muse, mutect2, varscan2
- ABCC4 | c.1624C>T p.R542W | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767916913; called by muse, mutect2, varscan2
- ADCY8 | c.1210C>T p.R404W | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV53903311; called by muse, mutect2, varscan2
- ADGRL2 | c.275T>G p.I92S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54655512; called by muse, mutect2, varscan2
- ADRA2B | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777494477; called by muse, mutect2, varscan2
- AMIGO3 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as COSV57537897; called by muse, mutect2, varscan2
- APOB | c.7558C>T p.R2520* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as rs746483297, COSV51944824; called by muse, mutect2, varscan2
- ASMT | c.727C>T p.P243S (on ENST00000381229; = p.P271S on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67110202; called by muse, mutect2, varscan2
- ATP9A | c.1753G>T p.E585* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV58767368; called by muse, mutect2, varscan2
- CCDC144A | c.3917C>T p.T1306M | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs775402588; called by muse, mutect2, varscan2
- CCDC15 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.068); catalogued as COSV61080815; called by muse, mutect2
- CCNB3 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs781990470, COSV52077131; called by muse, mutect2, varscan2
- CD109 | c.4162A>C p.R1388= | Splice Region (SNP) | VAF 17/41 reads (41%) | catalogued as COSV99752503; called by muse, mutect2, varscan2
- CDH4 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs771968638, COSV64658902; called by muse, mutect2, varscan2
- CLEC4F | c.1139A>G p.N380S | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.031); catalogued as rs1553395815; called by muse, mutect2, varscan2
- CNTNAP5 | c.1880A>G p.K627R | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as rs1185746482, COSV101444355; called by muse, mutect2, varscan2
- COG2 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs1318621157, COSV64188057; called by muse, mutect2, varscan2
- COL11A1 | c.5179A>C p.S1727R | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV62177375; called by muse, mutect2, varscan2
- CRAMP1 | c.3718G>T p.A1240S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1018206400; called by muse, mutect2, varscan2
- DNAH11 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs992756191, COSV60978170, COSV60985892; called by muse, mutect2, varscan2
- DROSHA | c.3637C>T p.R1213C | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV60772166; called by muse, mutect2
- DYNC2H1 | c.10184C>A p.T3395K | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62086184; called by muse, mutect2, varscan2
- EHMT2 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs139432784; called by muse, mutect2
- ENOX2 | c.320C>T p.T107M (on ENST00000338144 / NM_001382520.1; = p.T78M on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778753517; called by muse, mutect2, varscan2
- FAM111A | c.1688C>T p.T563I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs1243725179; called by muse, mutect2
- FAT4 | c.14673G>T p.K4891N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV58670244, COSV58682656; called by muse, mutect2, varscan2
- FCRL4 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.219); catalogued as COSV99619989; called by muse, mutect2, varscan2
- FFAR4 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs373550620; called by muse, mutect2, varscan2
- FGF6 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762919183, COSV99960129; called by muse, mutect2, varscan2
- FGF8 | c.589C>T p.P197S (on ENST00000344255 / NM_033164.4; = p.P179S on NM_006119.6) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as rs1324602839; called by muse, mutect2, varscan2
- FIGLA | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1453466936, COSV60089432; called by muse, mutect2, varscan2
- GAL | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs753843211; ClinVar: uncertain significance; called by mutect2, varscan2
- GALNT17 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); catalogued as rs367865697, COSV61147246; called by muse, mutect2, varscan2
- GLI3 | c.4652C>G p.S1551C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs1003879310; called by muse, mutect2, varscan2
- GLRA3 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV56862000; called by muse, mutect2, varscan2
- GPR148 | c.387C>A p.F129L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.353); catalogued as rs767065948, COSV59307477; called by muse, mutect2, varscan2
- HAPLN3 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs771290441; called by muse, mutect2, varscan2
- HAPLN4 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs1190803915, COSV52269227; called by muse, mutect2, varscan2
- HECW2 | c.465del p.C156Afs*4 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | catalogued as COSV53657186, COSV99645895; called by mutect2, pindel, varscan2
- ITGA8 | c.1699G>A p.V567I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs751705679, COSV65228078, COSV65230235; called by muse, mutect2, varscan2
- KATNIP | c.2404G>A p.E802K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs777793472; called by muse, mutect2, varscan2
- KNOP1 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs757928834, COSV54926546; called by muse, varscan2
- LRP2 | c.11371C>T p.R3791W | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759712755, COSV55539861; called by muse, mutect2, varscan2
- MAGEB3 | c.437A>G p.K146R | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs776429024, COSV100854760, COSV64397059; called by muse, mutect2
- MAGEB6B | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1456844558; called by muse, mutect2, varscan2
- MED1 | c.3995G>A p.S1332N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.026); catalogued as rs920656246; called by muse, mutect2, varscan2
- MGAT4B | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs752365931; called by muse, mutect2, varscan2
- MUC16 | c.14188G>A p.D4730N | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.065); catalogued as COSV67470105; called by muse, mutect2, varscan2
- MUC16 | c.10373C>T p.T3458I | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as rs748481060; called by muse, mutect2, varscan2
- MUC4 | c.15871C>T p.L5291= (on ENST00000463781 / NM_018406.7; = p.L1055= on NM_004532.6) | Splice Region (SNP) | VAF 14/52 reads (27%) | catalogued as rs746638492; called by muse, varscan2
- NCAM1 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs782083514, COSV100378550; called by muse, mutect2, varscan2
- NCKAP5 | c.5420G>A p.R1807H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs373366099, COSV58438529; called by muse, mutect2, varscan2
- NEK10 | c.1363C>G p.L455V | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs200628958; called by muse, mutect2, varscan2
- NKX2-5 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM044906, CM107631, COSV61299481; called by muse, mutect2, varscan2
- NPTN | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV104380506; called by muse, mutect2, varscan2
- OR10H1 | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 52/70 reads (74%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as COSV58472168; called by muse, mutect2, varscan2
- OR13C5 | c.817T>G p.L273V | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV66164122; called by muse, mutect2, varscan2
- OR5M8 | c.199T>C p.F67L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs1412632985; called by muse, mutect2, varscan2
- OTUD7B | c.2308C>T p.R770* | Nonsense Mutation (SNP) | VAF 25/65 reads (38%) | catalogued as rs587752377; called by muse, mutect2, varscan2
- PCDHB12 | c.2215G>A p.V739M | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.104); catalogued as rs1354810339; called by muse, mutect2, varscan2
- PDGFC | c.883C>A p.Q295K | Missense Mutation (SNP) | VAF 52/81 reads (64%) | SIFT tolerated (0.47); PolyPhen benign (0.109); catalogued as COSV56846398; called by muse, mutect2, varscan2
- PLPPR4 | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100926975; called by muse, mutect2, varscan2
- PTCHD3 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.82); PolyPhen benign (0.012); catalogued as rs1392627633, COSV101438916; called by muse, mutect2, varscan2
- PTPN13 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as COSV57413000; called by muse, mutect2, varscan2
- PTPN13 | c.5292A>T p.Q1764H (on ENST00000411767 / NM_080683.3; = p.Q1745H on NM_006264.3) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.332); catalogued as COSV104414288; called by muse, mutect2, varscan2
- PXDN | c.2614G>A p.G872R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs1380036826, COSV53246752; called by muse, mutect2, varscan2
- PYGB | c.1106C>T p.T369M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs201517237; called by mutect2, varscan2
- RABEPK | c.229T>G p.L77V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.096); catalogued as rs1240524886; called by muse, mutect2, varscan2
- RALY | c.369C>G p.F123L | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV55780050; called by muse, mutect2, varscan2
- RALY | c.400C>G p.L134V (on ENST00000246194 / NM_016732.3; = p.L118V on NM_007367.4) | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs368442158; called by muse, mutect2, varscan2
- RFX6 | c.1044T>G p.N348K | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.46); PolyPhen benign (0.05); catalogued as COSV60585078; called by muse, mutect2, varscan2
- RPL10L | c.235A>C p.S79R | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.049); catalogued as COSV53560159; called by muse, mutect2, varscan2
- SEMA3D | c.1109A>G p.N370S | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.714); catalogued as rs988907233; called by muse, mutect2, varscan2
- SEZ6 | c.1411C>A p.L471I | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1318190729; called by muse, mutect2, varscan2
- SLC12A9 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as rs200686276, COSV51933931; called by muse, mutect2, varscan2
- SMUG1 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as rs139760820; called by muse, mutect2, varscan2
- SNX31 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771586618; called by muse, mutect2, varscan2
- TCEA2 | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT tolerated (0.22); PolyPhen benign (0.133); catalogued as COSV58657383, COSV58659720; called by muse, mutect2, varscan2
- TGFBR2 | c.1178G>T p.C393F | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55450945, COSV55463216; called by muse, mutect2, varscan2
- TMEM200A | c.710A>C p.K237T | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.102); catalogued as COSV51649052; called by muse, mutect2
- TNS3 | c.3307C>T p.R1103W | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769760726; called by muse, varscan2
- TPTE | c.1178_1179del p.Y393Cfs*37 (on ENST00000618007 / NM_199261.4; = p.Y375Cfs*37 on NM_199259.4) | Frame Shift Del (DEL) | VAF 20/190 reads (11%) | catalogued as rs761585045; called by pindel, varscan2
- TRIM21 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs756422491; called by muse, mutect2, varscan2
- TRRAP | c.8749C>T p.R2917C (on ENST00000359863 / NM_001244580.1; = p.R2899C on NM_003496.3) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV62846010; called by muse, mutect2, varscan2
- TTN | c.50208A>C p.E16736D (on ENST00000591111; = p.E9312D on NM_003319.4) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | PolyPhen benign (0.006); catalogued as COSV59915047; called by muse, mutect2, varscan2
- UPF2 | c.2021_2024del p.T674Sfs*14 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs1488895098; called by pindel, varscan2
- WSCD1 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs1394035623, COSV58493531; called by muse, mutect2, varscan2
- ZNF677 | c.281T>G p.F94C | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); catalogued as COSV61720472; called by muse, mutect2, varscan2
- ZNF688 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.098); catalogued as rs775862905, COSV99794195; called by muse, mutect2, varscan2
- ABCA13 | c.15104del p.E5035Gfs*27 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | called by mutect2, pindel, varscan2
- ACAN | c.2212A>G p.N738D | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- ACSL5 | c.181C>T p.Q61* (on ENST00000354273; = p.Q117* on NM_016234.3) | Nonsense Mutation (SNP) | VAF 22/61 reads (36%) | called by muse, mutect2, varscan2
- ACTN2 | c.1928C>A p.A643D | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM7 | c.633+1G>T p.X211_splice | Splice Site (SNP) | VAF 21/32 reads (66%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.3487A>G p.R1163G | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGAP2 | c.1060A>G p.K354E | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ALAS2 | c.1268T>C p.L423P | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOB | c.12180A>C p.E4060D | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ARNT2 | c.880A>G p.M294V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH11 | c.1514T>C p.L505P | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- CLUH | c.713_722del p.Y238* (on ENST00000435359; = p.Y276* on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | called by mutect2, pindel, varscan2
- CNBD1 | c.1167del p.K389Nfs*58 | Frame Shift Del (DEL) | VAF 31/119 reads (26%) | called by mutect2, pindel, varscan2
- COL17A1 | c.2575C>T p.P859S | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL4A5 | c.1655C>A p.T552N | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CTSL | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCC | c.3532T>G p.S1178A | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- DEPTOR | c.997-1G>T p.X333_splice | Splice Site (SNP) | VAF 64/145 reads (44%) | called by muse, varscan2
- DIO2 | c.371T>C p.L124P | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH9 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, varscan2
- DNAH9 | c.12361G>A p.D4121N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- FCGBP | c.9322C>G p.L3108V | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- GCNT1 | c.86_88del p.F29del | In Frame Del (DEL) | VAF 14/67 reads (21%) | called by mutect2, pindel, varscan2
- GMPS | c.1231C>G p.L411V | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- HAND1 | c.384_395del p.K129_K132del | In Frame Del (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- IGHV3-64 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.279C>G p.N93K | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- IL31RA | c.270T>G p.T90= | Splice Region (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- KIF3A | c.1101A>G p.I367M | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- LRRC36 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- MDN1 | c.5061G>T p.K1687N | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MYLK2 | c.1144G>C p.D382H | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NAV1 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- NOX4 | c.1217A>G p.K406R | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- NUP42 | c.748del p.T250Qfs*144 | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | called by mutect2, varscan2
- OBSCN | c.7892C>T p.S2631F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- OBSCN | c.14589C>A p.S4863R | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR4N2 | c.761G>C p.G254A | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- OR5D13 | c.626A>C p.E209A | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- PABPC5 | c.137T>G p.F46C | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- PAXBP1 | c.1108dup p.T370Nfs*3 | Frame Shift Ins (INS) | VAF 15/53 reads (28%) | called by mutect2, pindel, varscan2
- PHF8 | c.1412G>A p.R471K (on ENST00000357988 / NM_001184896.1; = p.R435K on NM_015107.3) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPRC1 | c.1329_1330del p.N444Pfs*74 | Frame Shift Del (DEL) | VAF 8/25 reads (32%) | called by mutect2, pindel
- PRAMEF4 | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, varscan2
- PRAMEF5 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.101); called by muse, varscan2
- PRRG3 | c.161A>G p.E54G | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- RRAGB | c.311T>G p.F104C (on ENST00000262850 / NM_016656.4; = p.I76S on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- SCAF4 | c.3198_3201del p.R1066Sfs*17 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | called by mutect2, varscan2
- SKIL | c.436C>A p.Q146K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- SNAI2 | c.797T>C p.V266A | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNX27 | c.1468T>C p.Y490H | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TBCEL | c.530A>C p.K177T | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- TBX22 | c.1487A>T p.D496V | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- TCEANC2 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- TCHH | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | PolyPhen benign (0.305); called by muse, mutect2, varscan2
- TENM3 | c.436T>C p.C146R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TFIP11 | c.1576C>T p.Q526* | Nonsense Mutation (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- THSD7B | c.3875T>G p.L1292R (on ENST00000272643; = p.L1290R on NM_001316349.2) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM144 | c.75T>G p.N25K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TPP2 | c.2534A>G p.E845G | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRIM6 | c.428A>C p.K143T | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- TRPS1 | c.1302C>A p.Y434* (on ENST00000220888 / NM_001330599.2; = p.Y447* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- TSPAN7 | c.158A>G p.E53G | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- UBQLN2 | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- USP5 | c.506G>A p.W169* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- USP51 | c.560A>G p.E187G | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZCWPW2 | c.997T>G p.L333V | Missense Mutation (SNP) | VAF 74/93 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- ZNF329 | c.42A>C p.E14D | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ZNF43 | c.1895A>C p.N632T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZNF461 | c.827A>C p.N276T | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ABCA4 | c.4518C>T p.A1506= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs146011912; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB6 | c.2448G>A p.G816= | Silent (SNP) | VAF 14/52 reads (27%) | called by muse, mutect2, varscan2
- ADAMTS2 | c.3528A>G p.P1176= | Silent (SNP) | VAF 23/75 reads (31%) | called by muse, mutect2, varscan2
- ADGRG4 | c.6702T>G p.T2234= | Silent (SNP) | VAF 28/39 reads (72%) | called by muse, mutect2, varscan2
- ADGRG4 | c.6948A>G p.Q2316= | Silent (SNP) | VAF 28/45 reads (62%) | called by muse, mutect2, varscan2
- AKAP4 | c.1845G>A p.E615= | Silent (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- ARHGAP25 | c.951T>A p.I317= (on ENST00000409202 / NM_001007231.3; = p.I309= on NM_014882.3) | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as rs761519006; called by muse, mutect2, varscan2
- ARHGAP28 | c.1329T>C p.D443= (on ENST00000383472 / NM_001366230.1; = p.D284= on NM_001010000.3) | Silent (SNP) | VAF 14/26 reads (54%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.3261T>G p.S1087= (on ENST00000310343 / NM_001378025.1; = p.S738= on NM_014715.4) | Silent (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2, varscan2
- ARHGAP32 | c.2743C>T p.L915= (on ENST00000310343 / NM_001378025.1; = p.L566= on NM_014715.4) | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs1436182848; called by muse, mutect2, varscan2
- B4GALNT4 | c.426C>T p.H142= | Silent (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- BOD1L1 | c.3696T>C p.N1232= | Silent (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- BRINP2 | c.2205A>G p.K735= | Silent (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- CCDC184 | c.198C>T p.D66= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs1257891409; called by muse, mutect2, varscan2
- CCM2L | c.288G>A p.L96= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV52950433; called by muse, mutect2, varscan2
- CCN1 | c.957C>T p.D319= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs773361050; called by muse, mutect2, varscan2
- CD1B | c.738G>A p.Q246= | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as rs1171462889; called by muse, mutect2, varscan2
- CEL | c.2178C>A p.P726= (on ENST00000673714; = p.P723= on NM_001807.6) | Silent (SNP) | VAF 11/27 reads (41%) | called by mutect2, varscan2
- CHD1 | c.1350T>C p.P450= | Silent (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- CYB561D1 | c.636G>A p.V212= | Silent (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- DIP2B | c.2589G>A p.A863= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as rs756477912, COSV99999702; called by muse, mutect2, varscan2
- DNAH10 | c.10629C>T p.R3543= (on ENST00000409039; = p.R3482= on NM_207437.3) | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs760742102, COSV68999823; called by muse, mutect2, varscan2
- DPYSL3 | c.339G>A p.E113= | Silent (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- DSCAML1 | c.1683C>T p.N561= (on ENST00000321322; = p.N501= on NM_020693.4) | Silent (SNP) | VAF 29/49 reads (59%) | called by muse, mutect2, varscan2
- DTX3L | c.1191A>G p.S397= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs1177018521; called by muse, mutect2, varscan2
- DYNC2I2 | c.267G>A p.T89= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs137886760, COSV65548969; called by muse, mutect2, varscan2
- ELP1 | c.1656G>A p.A552= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs200535861; ClinVar: likely benign; called by muse, mutect2, varscan2
- EPS15L1 | c.975G>A p.T325= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs375758505; called by muse, mutect2, varscan2
- FAT4 | c.492C>T p.I164= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV101272664; called by muse, mutect2, varscan2
- FBXO43 | c.108G>A p.S36= | Silent (SNP) | VAF 37/52 reads (71%) | catalogued as rs779948648, COSV71053326; called by muse, mutect2, varscan2
- FRMD4A | c.2565C>T p.S855= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as COSV62269492; called by muse, mutect2, varscan2
- HLA-G | c.213G>A p.P71= | Silent (SNP) | VAF 27/106 reads (25%) | called by muse, mutect2, varscan2
- HOXA1 | c.972G>C p.G324= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV58031112; called by muse, mutect2
- HSPB6 | c.399G>A p.T133= | Silent (SNP) | VAF 25/35 reads (71%) | called by muse, mutect2, varscan2
- ISOC2 | c.483C>T p.S161= (on ENST00000425675 / NM_001136201.2; = p.S177= on NM_024710.3) | Silent (SNP) | VAF 41/108 reads (38%) | catalogued as rs781757125; called by muse, mutect2, varscan2
- ITGA4 | c.255C>T p.P85= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs780323276; called by muse, mutect2, varscan2
- KIR2DS4 | c.75C>A p.V25= | Silent (SNP) | VAF 57/126 reads (45%) | called by muse, mutect2, varscan2
- KRT32 | c.690C>G p.L230= | Silent (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- LUZP2 | c.804A>G p.Q268= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as COSV100419385, COSV61195719; called by muse, mutect2, varscan2
- MALSU1 | c.690G>A p.E230= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1562659293; called by muse, mutect2, varscan2
- MKI67 | c.2496G>A p.R832= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs754452741; called by muse, mutect2, varscan2
- MOB3C | c.183C>T p.A61= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs1398829383; called by muse, mutect2, varscan2
- MYH14 | c.2331C>T p.L777= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV51829078; called by muse, mutect2, varscan2
- NCKAP5 | c.4308T>C p.T1436= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV58431897; called by muse, mutect2, varscan2
- OBP2A | c.252G>A p.T84= | Silent (SNP) | VAF 42/158 reads (27%) | catalogued as rs372804933; called by muse, mutect2, varscan2
- OR4N2 | c.762C>T p.G254= | Silent (SNP) | VAF 6/109 reads (6%) | called by muse, mutect2
- PCDH8 | c.546C>T p.R182= | Silent (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- PCGF1 | c.504G>A p.Q168= | Silent (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- PDZD4 | c.1257G>A p.A419= | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as rs782730869, COSV99381687; called by muse, mutect2, varscan2
- PGLYRP4 | c.348C>T p.A116= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs1305904952, COSV62835296; called by muse, mutect2, varscan2
- PIGQ | c.1995C>T p.P665= | Silent (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2, varscan2
- PPEF1 | c.1905C>T p.F635= | Silent (SNP) | VAF 55/84 reads (65%) | called by muse, varscan2
- QTRT1 | c.474G>A p.L158= | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- RTP5 | c.54C>T p.A18= | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as rs759613968; called by muse, mutect2, varscan2
- SEC14L5 | c.1557C>T p.R519= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs780669380; called by muse, mutect2, varscan2
- SLC25A12 | c.1935G>A p.T645= | Silent (SNP) | VAF 46/85 reads (54%) | catalogued as rs369901246; called by muse, mutect2, varscan2
- SOGA3 | c.606C>T p.R202= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, varscan2
- SPATA31D1 | c.2421T>C p.T807= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV61192267; called by muse, mutect2, varscan2
- SRPX | c.1044C>A p.P348= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- TFAP2C | c.45C>T p.C15= | Silent (SNP) | VAF 26/158 reads (16%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.114A>G p.V38= | Silent (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- TRERF1 | c.3234C>T p.G1078= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs201886129, COSV61669744; called by muse, mutect2, varscan2
- TRIM67 | c.1314C>T p.T438= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs370010177; called by muse, mutect2, varscan2
- VWF | c.987C>T p.C329= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV54625388; called by muse, mutect2, varscan2
- ZFP28 | c.1284T>C p.T428= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV100019895, COSV56738164; called by muse, mutect2, varscan2
- ZNF521 | c.1281T>C p.T427= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs1248043118; called by muse, mutect2, varscan2
- AL136982.4 | n.741G>A | RNA (SNP) | VAF 44/218 reads (20%) | catalogued as rs774506857; called by muse, mutect2, varscan2
- BCAS3 | c.2639-3349del | Intron (DEL) | VAF 18/33 reads (55%) | catalogued as rs756350876, COSV66772038; called by mutect2, varscan2
- GABRG2 | c.1248+257G>T | Intron (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- IL19 | c.-55G>A | 5'UTR (SNP) | VAF 25/49 reads (51%) | catalogued as COSV100534748; called by muse, mutect2, varscan2
- LINC02843 | n.314T>C | RNA (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- NPR3 | c.*3114T>G | 3'UTR (SNP) | VAF 9/32 reads (28%) | catalogued as COSV54089417, COSV54089868; called by muse, mutect2, varscan2
- SOHLH1 | c.*612T>G | 3'UTR (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
